Somatic mutation profile of tumor specimen C3N-00859-01 (aliquot CPT0116010007) from CPTAC case C3N-00859, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.7 years (22,165 days).
Specimen C3N-00859-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 000dba39-93d0-4dd3-85cb-48307ddef813.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00859-31 (Blood Derived Normal), aliquot CPT0116130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47c88dff-3e9c-44d8-9f11-e7f9b82757d0

The open-access MAF lists 92 somatic variants for this specimen: 64 protein-altering or splice-affecting, 22 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 22, Nonsense Mutation 6, Intron 2, In Frame Ins 1, 5'UTR 1, 5'Flank 1, RNA 1, 3'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 43/388 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 72/207 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 30/200 reads (15%) | catalogued as rs587784098, CM031301, COSV100729678; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH1L1 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs755365962, COSV99856327; called by muse, varscan2
- ALDH1L1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as rs772606938; called by muse, mutect2, varscan2
- AMPH | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs772069356, COSV100340911, COSV57747907; called by muse, mutect2, varscan2
- CARD11 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1237589286, COSV62716241; called by muse, mutect2, varscan2
- CCL16 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs142115594; called by muse, mutect2
- CHD3 | c.4073-1G>T p.X1358_splice | Splice Site (SNP) | VAF 38/179 reads (21%) | catalogued as COSV57877790, COSV57881397; called by muse, mutect2, varscan2
- CLCN6 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 20/301 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56741421; called by muse, mutect2
- DMD | c.9563C>G p.T3188R | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100628359; called by muse, mutect2, varscan2
- EEF1A1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV58550449; called by muse, mutect2, varscan2
- FLG | c.7678A>T p.S2560C | Missense Mutation (SNP) | VAF 85/480 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV64238860; called by muse, mutect2, varscan2
- GALNT17 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.025); catalogued as rs998581287, COSV100356040, COSV61166877; called by muse, mutect2, varscan2
- GALNT5 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs1297174683; called by muse, mutect2, varscan2
- GBP4 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs138472408; called by muse, varscan2
- ITIH3 | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs762645645, COSV99820054; called by muse, mutect2, varscan2
- LECT2 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs140811147; called by muse, mutect2, varscan2
- LRRN3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs951604736; called by muse, mutect2, varscan2
- NFIC | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs548567332; called by muse, mutect2, varscan2
- NTNG2 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 87/468 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753949417, COSV100647589; called by muse, mutect2, varscan2
- PLXNB2 | c.4034G>A p.R1345H | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63780926; called by muse, mutect2, varscan2
- SCN4A | c.3703C>T p.L1235F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1218047325; called by muse, mutect2
- SGSM2 | c.2875C>T p.R959* (on ENST00000426855 / NM_001098509.2; = p.R1004* on NM_014853.3) | Nonsense Mutation (SNP) | VAF 34/192 reads (18%) | catalogued as rs867998099; called by muse, mutect2, varscan2
- SH3RF1 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1366390543; called by muse, mutect2
- SLC6A16 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1419369998; called by muse, mutect2, varscan2
- SLITRK5 | c.2258C>A p.P753H | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100280273, COSV61526016; called by muse, mutect2, varscan2
- SRRM2 | c.5840G>A p.R1947H | Missense Mutation (SNP) | VAF 67/403 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs200895450, COSV57071932, COSV57079412; called by muse, mutect2, varscan2
- SUFU | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.983); catalogued as COSV64015189; called by muse, mutect2
- TLE6 | c.1592C>T p.P531L (on ENST00000246112 / NM_001143986.2; = p.P408L on NM_024760.3) | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs200522179, COSV53579943; called by muse, mutect2
- WDR27 | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV61216286; called by muse, mutect2, varscan2
- ZNF16 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 49/359 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs371831481; called by muse, mutect2, varscan2
- ZNF79 | c.999C>G p.Y333* | Nonsense Mutation (SNP) | VAF 61/308 reads (20%) | catalogued as COSV100688222; called by muse, mutect2, varscan2
- ADRA2A | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ATP1A2 | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 83/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C1orf198 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 38/233 reads (16%) | called by muse, mutect2, varscan2
- CDK10 | c.467_470dup p.N157Kfs*53 (on ENST00000353379 / NM_052988.5; = p.N86Kfs*53 on NM_052987.4) | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- CFAP43 | c.4004C>T p.P1335L | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.153); called by muse, mutect2
- DSE | c.746A>T p.E249V | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- EVX1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2
- FAM193A | c.378C>A p.S126R | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FAM50A | c.148T>C p.S50P | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); called by muse, mutect2
- FAT4 | c.2023A>T p.I675L | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2
- FOS | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 93/602 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- GIMAP4 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- HMCN2 | c.15017G>A p.R5006H | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- INTS1 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 26/493 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2
- KBTBD12 | c.1225T>C p.Y409H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- LILRA6 | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- MCF2 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- MROH7 | c.1906_1908dup p.I636dup | In Frame Ins (INS) | VAF 18/108 reads (17%) | called by mutect2, varscan2
- MUC22 | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 47/418 reads (11%) | SIFT tolerated (0.22); called by muse, mutect2, varscan2
- NLGN4X | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- NSD1 | c.6475T>C p.C2159R | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUP210L | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- P2RX3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- PCDHB5 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 15/497 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHG3 | c.2491C>G p.L831V (on ENST00000394691; = p.L887V on NM_001308147.2) | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC41A3 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SMG9 | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SSX3 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYNGAP1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 45/694 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRPM3 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- VWF | c.976G>C p.V326L | Missense Mutation (SNP) | VAF 82/490 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AIFM2 | c.465G>A p.V155= | Silent (SNP) | VAF 137/436 reads (31%) | called by muse, mutect2, varscan2
- CPA5 | c.1308C>T p.Y436= | Silent (SNP) | VAF 33/300 reads (11%) | called by muse, mutect2, varscan2
- DAND5 | c.105T>C p.A35= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- FASLG | c.177G>A p.P59= | Silent (SNP) | VAF 24/454 reads (5%) | catalogued as rs559795993, COSV60679598; ClinVar: benign; called by muse, mutect2
- GNAS | c.1323C>A p.P441= | Silent (SNP) | VAF 32/468 reads (7%) | catalogued as rs146744182; called by muse, mutect2
- GRAMD1B | c.1974C>T p.T658= | Silent (SNP) | VAF 15/441 reads (3%) | catalogued as rs914868976; called by muse, mutect2
- GRTP1 | c.846C>T p.S282= | Silent (SNP) | VAF 69/404 reads (17%) | catalogued as rs770695889; called by muse, mutect2, varscan2
- HCFC1 | c.5925C>T p.T1975= | Silent (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- HSPA1L | c.807C>T p.C269= | Silent (SNP) | VAF 86/553 reads (16%) | catalogued as rs576696139; called by muse, mutect2, varscan2
- MAOA | c.1326C>T p.S442= | Silent (SNP) | VAF 49/431 reads (11%) | catalogued as rs771100973, COSV58642225; called by muse, mutect2, varscan2
- MCTP2 | c.78G>A p.K26= | Silent (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- MGLL | c.756G>A p.E252= (on ENST00000398104 / NM_001003794.2; = p.E262= on NM_007283.6) | Silent (SNP) | VAF 39/388 reads (10%) | called by muse, mutect2
- MYL1 | c.375C>T p.D125= | Silent (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- MYRF | c.3276T>C p.S1092= (on ENST00000278836 / NM_001127392.3; = p.S1052= on NM_013279.4) | Silent (SNP) | VAF 44/239 reads (18%) | called by muse, mutect2, varscan2
- PAPPA2 | c.613C>A p.R205= | Silent (SNP) | VAF 34/202 reads (17%) | catalogued as rs1467869802, COSV62775190; called by muse, mutect2, varscan2
- PCDHA3 | c.2055C>T p.G685= | Silent (SNP) | VAF 47/214 reads (22%) | catalogued as rs1554122674; called by muse, mutect2, varscan2
- PRAM1 | c.1185G>A p.A395= | Silent (SNP) | VAF 27/208 reads (13%) | called by muse, mutect2, varscan2
- RBBP6 | c.5184G>A p.K1728= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs145169033; called by muse, mutect2, varscan2
- SF3A2 | c.336C>T p.I112= | Silent (SNP) | VAF 43/299 reads (14%) | catalogued as rs146189137, COSV55555639; called by muse, mutect2, varscan2
- SPEN | c.837C>T p.S279= | Silent (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2
- TRAPPC10 | c.2991C>A p.S997= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- ZNF320 | c.1236T>C p.L412= | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- IGSF9B | chr11:133956763 C>A | 5'Flank (SNP) | VAF 32/191 reads (17%) | catalogued as rs900245280; called by muse, mutect2, varscan2
- MLIP | c.612+11899C>A | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- MMP26 | c.-145+92763G>T | Intron (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- SNORD116-17 | n.3A>C | RNA (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- THSD4 | c.*3351C>T | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- UNCX | c.-4C>T | 5'UTR (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2
